MMRF case MMRF_2517 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/94b897d9-207d-4f74-b413-83452cf42172

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.0 years (20,811 days); ISS stage: I; Days to last known disease status: 673 days (1.8 years); Days to last follow up: 673 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 120 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 171 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 0): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.939 mg/dL; Immunoglobulin G 44.9 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.43 µg/mL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.06 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.46 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 9.6 g/dL; C-Reactive Protein 0.3 mg/dL.
- Day 85 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.852 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 12.2 ×10⁹/L; Absolute Neutrophil 10.3 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.89 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL.
- Day 155: M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 1.93 g/L; Immunoglobulin M 0.77 g/L; Beta 2 Microglobulin 1.43 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.27 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 7.4 g/dL; Glucose 6.22 mmol/L.
- Day 260: Serum Free Immunoglobulin Light Chain, Kappa 0.627 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 7.11 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.61 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL.
- Day 337: Serum Free Immunoglobulin Light Chain, Kappa 0.747 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 6.9 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.27 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.53 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL.
- Day 450 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 8.75 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.39 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.68 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL.
- Day 510 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.13 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.75 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL.
- Day 575 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.55 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.36 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL.
- Day 673 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.68 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.28 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL.

Other clinical attributes
- Day -19: Weight: 95 kg; Height: 174 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2517_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2517_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
